Surgical pathology report (de-identified scan), TCGA case TCGA-E1-A7YQ, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Duke, specimen TCGA-E1-A7YQ-01A (Primary Tumor).

Patient: [REDACTED]

Surgical Pathology: Final [REDACTED] Acc# [REDACTED]

Surg Path

CLINICAL HISTORY:
Not provided.

GROSS EXAMINATION:

A. "Brain tumor (Afl);", received fresh for frozen section. A 0.5 x 0.5 x 0.4 cm aggregate of tan-brown tissue is received. Several of the fragments have been previously submitted as frozen section Afl. The frozen section remnant is submitted in A1. The remaining and frozen tissue is submitted in A2.

B. "Brain tumor", received fresh and placed in formalin. A 2 x 1.3 x 0.6 cm aggregate of three irregular fragment of tan-brown tissue is received. Representative retained in formalin and the remainder is submitted in B1.

C. "Brain tumor", received fresh and placed in formalin. An 8 x 6 x 2.5 cm aggregate of multiple fragments of tissue grossly consistent with brain including gray and white matter as well as more amorphous rubbery pink-tan tissue is received. Multiple representatives are submitted in C1-C6 (predominantly normal brain in C5 and C6).

INTRA OPERATIVE CONSULTATION:

A. "Brain tumor": Afl-high-grade glioma (Dr.

MICROSCOPIC EXAMINATION:

The tissue is multiple portions of brain infiltrated by a neoplastic proliferation of glial cells. The tumor cells commonly exhibit a minigemistocytic appearance. In the periphery, tumor cells infiltrate in the surrounding cortex in individual cells and often exhibit perineuronal satellitosis. Areas of necrosis are admist densely cellular tumor are evident.

DIAGNOSIS:

A. "BRAIN TUMOR":

ANAPLASTIC OLIGODENDROGLIOMA (WHO GRADE III).

B. "BRAIN TUMOR":

ANAPLASTIC OLIGODENDROGLIOMA (WHO GRADE III).

C. "BRAIN TUMOR":

ANAPLASTIC OLIGODENDROGLIOMA (WHO GRADE III).

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

Electronically signed: [REDACTED]

ICD O.3
Oligodendroglioma, grade III
CNE 9/15/13
Site: Brain, supratentorial NOS
with Brain NOS 9/21/9
9/25/14

Source: NCI Genomic Data Commons file 7dd278f0-da58-4a0c-9745-84637e3b3a27 (TCGA-E1-A7YQ.FECABDF2-3EBF-4C3C-AEAD-08D5494852FA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).